Somatic mutation profile of tumor specimen TCGA-B6-A0I5-01A (aliquot TCGA-B6-A0I5-01A-11W-A100-09) from TCGA case TCGA-B6-A0I5, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 49.4 years (18,038 days).
Specimen TCGA-B6-A0I5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7c32350-14f0-41f6-901e-23030c5df95a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0I5-10A (Blood Derived Normal), aliquot TCGA-B6-A0I5-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/458dc8fb-e537-4306-b8c1-0463092b73a7

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Splice Region 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 36/110 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.2476G>A p.G826S | Missense Mutation (SNP) | VAF 78/215 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1288025890, COSV56855212; called by muse, mutect2, varscan2
- ABCD2 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs779301167, COSV100429819, COSV58049287; called by muse, mutect2, varscan2
- ADAM23 | c.654T>C p.L218= | Splice Region (SNP) | VAF 12/225 reads (5%) | catalogued as COSV100008376; called by muse, mutect2
- ANKRD12 | c.5044A>G p.I1682V | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as rs372100647; called by muse, mutect2, varscan2
- ASH1L | c.3368G>T p.S1123I | Missense Mutation (SNP) | VAF 11/388 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100853548; called by muse, mutect2
- CNP | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV57269911; called by muse, mutect2, varscan2
- FADS2 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV53901080; called by muse, mutect2, varscan2
- FLG | c.6089C>A p.A2030E | Missense Mutation (SNP) | VAF 60/308 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.071); catalogued as rs750432891, COSV64245847; called by muse, mutect2, varscan2
- L3MBTL4 | c.984T>C p.V328= | Splice Region (SNP) | VAF 160/478 reads (33%) | catalogued as COSV53134653; called by muse, varscan2
- MCHR2 | c.788G>A p.S263N | Missense Mutation (SNP) | VAF 32/759 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as COSV99912465; called by muse, mutect2
- MPP7 | c.298T>C p.S100P | Missense Mutation (SNP) | VAF 151/486 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV61736132; called by muse, mutect2, varscan2
- NCAN | c.3068G>A p.C1023Y | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99387938; called by muse, mutect2
- PDAP1 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 164/360 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV63299613; called by muse, mutect2, varscan2
- PKHD1L1 | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 241/434 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs200017885, COSV65742348; called by muse, mutect2, varscan2
- SFMBT1 | c.1293T>G p.S431R | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV56256265; called by muse, mutect2, varscan2
- ZNF454 | c.1418G>C p.C473S | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60769590; called by muse, varscan2
- KMT2D | c.11574_11582del p.Q3861_Q3863del | In Frame Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- CRYGD | c.246C>T p.I82= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs1317721481, COSV52205843; called by muse, mutect2, varscan2
- CSMD1 | c.9186T>C p.Y3062= (on ENST00000520002; = p.Y3061= on NM_033225.6) | Silent (SNP) | VAF 51/288 reads (18%) | catalogued as COSV59360899; called by muse, mutect2, varscan2
- KIAA1755 | c.1947C>T p.S649= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs1432413644, COSV54078853; called by muse, mutect2, varscan2
- MYO5B | c.4374G>A p.T1458= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as rs373704566; called by muse, mutect2, varscan2
- SNX31 | c.507G>A p.K169= | Silent (SNP) | VAF 11/274 reads (4%) | catalogued as COSV61262683; called by muse, mutect2
- PKD1L2 | n.3153C>A | RNA (SNP) | VAF 41/230 reads (18%) | catalogued as rs771221155; called by muse, mutect2, varscan2
